Somatic mutation profile of tumor specimen BA2500D (aliquot aq-BA2500D) from BEATAML1.0 case 2120, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Primary diagnosis: Acute promyelocytic leukaemia, PML-RAR-alpha; Tissue or organ of origin: Bone marrow; Age at diagnosis: 59.3 years (21,663 days).
Specimen BA2500D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa9bd766-69e3-4509-a105-deec8ca54e21.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2279D (Solid Tissue Normal), aliquot aq-BA2279D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e607508-2ffa-4397-bfb0-6fd4b04df27b

The open-access MAF lists 16 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 4, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD33 | c.501C>A p.S167R (on ENST00000340970 / NM_001304459.2; = p.S292R on NM_182608.4) | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.383); catalogued as COSV56605439; called by muse, mutect2
- AOC1 | c.376C>G p.R126G | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as rs181034632, COSV62869534; called by muse, mutect2, varscan2
- CLTCL1 | c.1333A>G p.K445E | Missense Mutation (SNP) | VAF 91/182 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.777); catalogued as rs1555960180; called by muse, mutect2, varscan2
- PAPPA2 | c.2773G>A p.E925K | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.233); catalogued as rs191519115; called by muse, mutect2
- ABCF3 | c.1976G>A p.G659D | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ASB16 | c.749C>A p.A250E | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ME1 | c.67C>T p.H23Y | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR1G1 | c.872G>T p.S291I | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.084); called by muse, mutect2
- SYT4 | c.719T>C p.F240S | Missense Mutation (SNP) | VAF 91/210 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF732 | c.1184G>T p.C395F | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CYP2D6 | c.123C>T p.P41= | Silent (SNP) | VAF 97/326 reads (30%) | catalogued as rs146558635; called by muse, mutect2, varscan2
- ITSN1 | c.4380G>A p.P1460= | Silent (SNP) | VAF 37/85 reads (44%) | catalogued as rs776757634, COSV67156992; called by muse, mutect2, varscan2
- MAJIN | c.438C>T p.D146= | Silent (SNP) | VAF 55/117 reads (47%) | catalogued as rs145232114; called by muse, mutect2, varscan2
- TRIM35 | c.1284G>T p.L428= | Silent (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- FGG | c.308-51T>C | Intron (SNP) | VAF 126/243 reads (52%) | called by muse, mutect2, varscan2
- TMPRSS3 | c.*221del | 3'UTR (DEL) | VAF 89/186 reads (48%) | called by mutect2, varscan2
